Somatic mutation profile of tumor specimen TCGA-A5-A7WK-01A (aliquot TCGA-A5-A7WK-01A-11D-A34Q-09) from TCGA case TCGA-A5-A7WK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.3 years (26,044 days).
Specimen TCGA-A5-A7WK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b97c0a2-6a1a-426d-a49c-6236b3be4f74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A7WK-10A (Blood Derived Normal), aliquot TCGA-A5-A7WK-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3e3ecf9-5c03-4635-8f23-19c50c693423

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Frame Shift Del 2, 5'UTR 2, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 83/85 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.1155G>C p.E385D (on ENST00000379869 / NM_001079858.3; = p.E382D on NM_005756.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV100492418; called by muse, mutect2, varscan2
- ALDH16A1 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99513041; called by mutect2, varscan2
- ANKRD7 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV99501219; called by muse, mutect2, varscan2
- APLP1 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as rs1292323235, COSV99384143; called by muse, mutect2, varscan2
- ARHGAP36 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV99357889; called by muse, mutect2, varscan2
- ASB10 | c.739G>A p.E247K (on ENST00000420175 / NM_001142459.2; = p.E232K on NM_080871.4) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs764009407, COSV51994203; called by muse, mutect2, varscan2
- BAG1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101116714; called by muse, mutect2, varscan2
- BRWD1 | c.6094C>A p.H2032N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1461882103, COSV100313690; called by muse, mutect2
- CHFR | c.1477C>T p.P493S (on ENST00000432561 / NM_001161345.1; = p.P452S on NM_018223.2) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1187706335, COSV57177584; called by muse, mutect2
- CLDN12 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.549); catalogued as rs970708263; called by muse, mutect2
- COL6A3 | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV55089167, COSV99799598; called by muse, mutect2, varscan2
- COLEC12 | c.1811A>G p.D604G | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.242); catalogued as COSV101232111; called by muse, mutect2, varscan2
- DNAH10 | c.1102G>A p.D368N (on ENST00000409039; = p.D307N on NM_207437.3) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101292387; called by muse, mutect2, varscan2
- DNAH9 | c.6494A>C p.H2165P | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV99306722; called by muse, mutect2, varscan2
- ERICH3 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100444909; called by muse, mutect2, varscan2
- FAM102B | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 105/168 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1193365654, COSV64239626; called by muse, mutect2, varscan2
- FAM120B | c.2419G>T p.G807W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99379583; called by mutect2, varscan2
- FHOD3 | c.3311C>A p.A1104E (on ENST00000359247 / NM_001281739.3; = p.A1121E on NM_025135.5) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99941786; called by muse, mutect2, varscan2
- FMR1 | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99503492; called by muse, mutect2, varscan2
- GBP7 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643252; called by muse, mutect2, varscan2
- GCG | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV100972800; called by muse, mutect2, varscan2
- GPRASP1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100851029; called by muse, mutect2, varscan2
- H3-5 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100461701; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV54566802; called by muse, mutect2, varscan2
- IGSF9B | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.345); catalogued as COSV100317989; called by muse, mutect2, varscan2
- KIF2C | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV100945767; called by muse, mutect2, varscan2
- MYOM2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs200858192, COSV100037849; called by muse, mutect2, varscan2
- OR2G6 | c.518C>A p.T173K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100598240; called by muse, mutect2, varscan2
- OR5H6 | c.100T>G p.L34V (on ENST00000642105; = p.L18V on NM_001005479.2) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV101051791; called by muse, mutect2
- PDZD8 | c.993C>A p.S331R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1212986859; called by muse, mutect2
- PPP2R1A | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV59044929; called by muse, mutect2, varscan2
- QSER1 | c.3016G>C p.E1006Q (on ENST00000399302; = p.E1135Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV101234687, COSV101234894; called by muse, mutect2
- SETD2 | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV100339421, COSV57431489; called by muse, mutect2, varscan2
- SIKE1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs762957321, COSV99285323; called by muse, mutect2, varscan2
- SLC22A9 | c.246C>G p.N82K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99655152; called by muse, mutect2, varscan2
- SLC22A9 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99655155; called by muse, mutect2, varscan2
- SPG7 | c.1204G>A p.E402K (on ENST00000268704; = p.E409K on NM_003119.4) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD152072, COSV51950394; called by muse, mutect2, varscan2
- STK31 | c.1494T>G p.F498L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63455164; called by muse, mutect2, varscan2
- TAF1B | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as COSV99722287; called by muse, mutect2, varscan2
- TMEM132D | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV70607402; called by muse, mutect2, varscan2
- TNRC18 | c.8779G>C p.E2927Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs992210521, COSV99032741; called by muse, mutect2, varscan2
- TPSG1 | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99326870; called by muse, mutect2, varscan2
- TRAF3 | c.129T>A p.F43L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100693659; called by muse, mutect2, varscan2
- TRPA1 | c.2143G>C p.G715R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100084592; called by muse, mutect2, varscan2
- UGT1A7 | c.479A>T p.Y160F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV100692986; called by muse, mutect2, varscan2
- WDR17 | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as rs142589281; called by muse, mutect2, varscan2
- ZNF516 | c.372C>G p.C124W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101487316; called by muse, varscan2
- ZNF75D | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100883672; called by muse, mutect2, varscan2
- ARHGAP35 | c.2515del p.S839Hfs*48 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | called by mutect2, pindel, varscan2
- BCL11A | c.602del p.N201Ifs*7 (on ENST00000335712 / NM_001365609.1; = p.N235Ifs*7 on NM_018014.4) | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- PRCC | c.1323+2dup p.X441_splice | Splice Site (INS) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- REV3L | c.1215C>A p.F405L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, varscan2
- SSU72P8 | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CBFA2T2 | c.1569C>T p.I523= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs766207717, COSV60801610; called by muse, mutect2, varscan2
- CBX8 | c.708C>T p.S236= | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as rs138089335; called by muse, mutect2, varscan2
- DUOX1 | c.2346C>T p.D782= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs559724860, COSV58485248; called by muse, mutect2, varscan2
- GREB1 | c.291C>T p.A97= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs778748402, COSV99303222; called by muse, mutect2, varscan2
- HCN1 | c.357G>A p.A119= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100297727; called by muse, mutect2, varscan2
- ITGA9 | c.1449C>T p.H483= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs766014507, COSV53243369; called by muse, mutect2, varscan2
- NOS1 | c.1416C>T p.D472= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs767679892, COSV57606066; called by muse, mutect2, varscan2
- OR1L1 | c.228G>A p.P76= (on ENST00000373686; = p.P26= on NM_001005236.3) | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs778038956, COSV100542217; called by muse, varscan2
- OR5W2 | c.903G>C p.L301= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100747674; called by muse, mutect2, varscan2
- PDE9A | c.1188T>C p.P396= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99371823; called by muse, mutect2, varscan2
- RBM5 | c.498T>A p.I166= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100762378; called by muse, mutect2, varscan2
- SFI1 | c.1305A>G p.R435= (on ENST00000400288 / NM_001007467.3; = p.R404= on NM_014775.4) | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101192156; called by muse, mutect2, varscan2
- SMU1 | c.438C>T p.A146= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs1234551187, COSV101238555; called by muse, mutect2, varscan2
- TRAIP | c.1065G>A p.K355= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV58913087; called by muse, mutect2, varscan2
- WNK3 | c.9T>C p.T3= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100671658; called by muse, mutect2, varscan2
- ZNF28 | c.444G>C p.L148= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV100354567; called by muse, mutect2, varscan2
- CTBP2 | c.58+11404G>A | Intron (SNP) | VAF 20/25 reads (80%) | catalogued as rs201365198, COSV100456633; called by muse, mutect2, varscan2
- IFNG | c.-1G>A | 5'UTR (SNP) | VAF 25/58 reads (43%) | catalogued as rs776667149, COSV57491332; called by muse, mutect2, varscan2
- RGP1 | c.-45C>G | 5'UTR (SNP) | VAF 74/252 reads (29%) | catalogued as COSV100960272; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+537_-31+539dup | Intron (INS) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
